Gene-level copy-number profile of tumor specimen ALCH-B1OB-TTP1-A from ALCHEMIST case ALCH-B1OB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.0 years (25,941 days).
Specimen ALCH-B1OB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09a88eb4-60ff-41a6-b1f7-8ded53d711bd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1OB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/7a8317e8-40be-40a7-9fa8-637afcbcb130

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 17,172; copy number 2: 32,376; copy number 3: 5,366; copy number 4: 3,264; copy number 5: 385; copy number 6: 153; copy number 7: 54; copy number 8: 18; copy number 9: 14; copy number 11: 35; copy number 12: 11.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–53,312, 1 gene: OR4G4P.
- chr1:89,551–91,105, 1 gene (within-gene range 0–2): AL627309.3.
- chr4:154,523,487–154,524,807, 1 gene: AC110753.1.
- chr5:135,038,831–135,040,047, 1 gene (within-gene range 0–1): C5orf66-AS1.
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr11:114,521,645–115,128,373, 6 genes (within-gene range 0–1): NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2, AP003179.1.
- chr12:6,155,035–6,160,719, 1 gene: AC005845.1.
- chr13:30,880,912–32,778,019, 29 genes (within-gene range 0–1): LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4.
- chr17:18,415,728–18,425,097, 2 genes: KRT17P5, YWHAEP2.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 670 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:223,538,007–223,665,723, 2 genes, copy number 5: CAPN8, SNRPEP10.
- chr5:1,173,141–1,634,005, 19 genes, copy number 6: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr5:13,144,000–43,707,405, 424 genes, copy number 5–7 (broad region; genes not listed).
- chr5:52,673,186–58,863,414, 117 genes, copy number 5–12 (broad region; genes not listed).
- chr5:62,306,162–62,628,582, 9 genes, copy number 6: KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3, AC114982.1, RPL35AP14, LRRC70.
- chr6:37,170,152–37,394,734, 8 genes, copy number 6: PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P.
- chr11:66,067,277–66,069,619, 1 gene, copy number 6 (within-gene range 2–6): AP006287.2.
- chr14:18,333,726–18,341,859, 1 gene, copy number 8: CR383658.1.
- chr19:1,852,399–1,863,579, 2 genes, copy number 6 (within-gene range 1–6): KLF16, AC012615.4.
- chr21:43,414,483–43,453,902, 2 genes, copy number 8: SIK1, LINC00319.
- chr22:18,715,815–18,719,341, 1 gene, copy number 5: PPP1R26P4.
- chr22:22,689,831–23,717,356, 84 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,324. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
